Gene-level copy-number profile of tumor specimen TCGA-OR-A5JI-01A from TCGA case TCGA-OR-A5JI, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 22.4 years (8,177 days).
Specimen TCGA-OR-A5JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.0e68b520-96e7-402c-a522-64995ea316a5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00469487-8667-48a6-bfbe-3222b31db311

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,767; copy number 3: 14,539; copy number 4: 25,989; copy number 5: 40; copy number 6: 16,484.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JI-01A-11D-A29H-01): tumor purity 0.62, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
